Somatic mutation profile of tumor specimen TARGET-10-PARBRX-09A (aliquot TARGET-10-PARBRX-09A-01D) from TARGET case TARGET-10-PARBRX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,367 days).
Specimen TARGET-10-PARBRX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb3a804b-423e-4a97-8e8b-a71eac2b68ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBRX-10A (Blood Derived Normal), aliquot TARGET-10-PARBRX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42e6d585-82f1-4a13-8e8c-31d456936d06

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 2, Frame Shift Ins 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>C p.G1366R | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- AJUBA | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- PCNX3 | c.1675dup p.E559Gfs*92 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by pindel, varscan2
- UNC13C | c.6619A>T p.T2207S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.492); called by muse, varscan2
- COL5A2 | c.3604C>A p.R1202= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV100880869; called by muse, mutect2, varscan2
- MXRA5 | c.5730C>T p.N1910= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs767659217, COSV99479079; called by muse, mutect2, varscan2
- BCL11B | c.*41G>A | 3'UTR (SNP) | VAF 12/30 reads (40%) | catalogued as rs779336523; called by muse, mutect2, varscan2
- IGHM | c.1300+62_1300+75del | Intron (DEL) | VAF 35/85 reads (41%) | called by mutect2, pindel, varscan2
- NRXN3 | c.-52C>T | 5'UTR (SNP) | VAF 11/53 reads (21%) | catalogued as COSV101626842; called by muse, mutect2, varscan2
- PITRM1 | c.2917+155C>T | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, varscan2
